Somatic mutation profile of tumor specimen MP2PRT-PAVLKS-TMP1-A (aliquot MP2PRT-PAVLKS-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVLKS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (961 days).
Specimen MP2PRT-PAVLKS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e09270e-f526-4288-b424-8af7c24a0de2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVLKS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVLKS-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1bca303a-6abe-4cde-9f5e-a1154d4f681d

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR3 | c.2116G>A p.G706S | Missense Mutation (SNP) | VAF 123/274 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51167330; called by muse, mutect2, varscan2
- CHST6 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 197/452 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762397644, COSV59999475; called by muse, mutect2, varscan2
- EXOC2 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 132/456 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs202216214; called by muse, mutect2, varscan2
- FLT3 | c.1975A>G p.M659V | Missense Mutation (SNP) | VAF 102/270 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as rs753200838, COSV99610173; called by muse, mutect2, varscan2
- JAKMIP2 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 94/212 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as COSV54601725; called by muse, mutect2, varscan2
- PDZD2 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 136/339 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs1349219361; called by muse, mutect2, varscan2
- ANKRD31 | c.5488G>A p.E1830K | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- CAT | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 87/258 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC144A | c.1259A>C p.N420T | Missense Mutation (SNP) | VAF 113/272 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- CFAP61 | c.2861G>T p.C954F | Missense Mutation (SNP) | VAF 91/257 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- KIF13A | c.3499C>T p.P1167S | Missense Mutation (SNP) | VAF 97/347 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRIM69 | c.967T>C p.S323P (on ENST00000329464 / NM_182985.5; = p.S164P on NM_080745.5) | Missense Mutation (SNP) | VAF 111/253 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- C22orf31 | c.42C>T p.I14= | Silent (SNP) | VAF 129/303 reads (43%) | called by muse, mutect2
- CAPN10 | c.1980C>T p.F660= | Silent (SNP) | VAF 12/429 reads (3%) | catalogued as COSV54374636; called by muse, mutect2
- FAM171B | c.504G>A p.P168= | Silent (SNP) | VAF 12/257 reads (5%) | catalogued as rs1240236792; called by muse, mutect2
- MTMR14 | c.243C>T p.I81= | Silent (SNP) | VAF 142/335 reads (42%) | catalogued as rs1467663583, COSV56004255; called by muse, mutect2, varscan2
- MYBL1 | c.1173C>T p.T391= | Silent (SNP) | VAF 163/594 reads (27%) | called by muse, mutect2, varscan2
- UNC5A | c.267C>T p.I89= | Silent (SNP) | VAF 23/293 reads (8%) | catalogued as rs765661556, COSV56170903; called by muse, mutect2
- RAB11FIP5 | c.1569-4262C>T | Intron (SNP) | VAF 133/380 reads (35%) | called by muse, mutect2, varscan2
- SPATS2L | c.*1532G>A | 3'UTR (SNP) | VAF 92/215 reads (43%) | called by muse, mutect2, varscan2
